Somatic mutation profile of tumor specimen TCGA-VR-A8EU-01A (aliquot TCGA-VR-A8EU-01A-11D-A36J-09) from TCGA case TCGA-VR-A8EU, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 51.2 years (18,711 days).
Specimen TCGA-VR-A8EU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 022115c6-79a4-4156-bc6a-6bb2a797545e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VR-A8EU-10A (Blood Derived Normal), aliquot TCGA-VR-A8EU-10A-01D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/54563e65-cad0-4a17-9f95-d3f0986ba81c

The open-access MAF lists 108 somatic variants for this specimen: 77 protein-altering or splice-affecting, 28 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 28, Nonsense Mutation 6, RNA 3, In Frame Del 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.764_766del p.I255del | In Frame Del (DEL) | VAF 18/28 reads (64%) | hotspot (GDC flag); catalogued as rs1064794309; called by pindel, varscan2
- ABCA1 | c.5773C>T p.R1925W | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs568280586, COSV66068709; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACCSL | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.477); catalogued as rs199907490; called by muse, mutect2, varscan2
- CCDC160 | c.789G>T p.M263I | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV66251642; called by muse, mutect2, varscan2
- CCP110 | c.392C>T p.T131M | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.577); catalogued as rs372440972; called by muse, mutect2, varscan2
- DLGAP2 | c.2837C>T p.A946V | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV70096705; called by muse, mutect2, varscan2
- FAT4 | c.4352T>C p.I1451T | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.974); catalogued as COSV67891871; called by muse, mutect2, varscan2
- HCAR2 | c.715G>A p.V239I | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.954); catalogued as rs750950242; called by muse, mutect2, varscan2
- HCRTR2 | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.022); catalogued as COSV63796188; called by muse, mutect2, varscan2
- IKBKE | c.2116C>T p.R706W | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs782670085; called by muse, mutect2, varscan2
- KALRN | c.5327G>A p.R1776H (on ENST00000360013 / NM_001024660.4; = p.R79H on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs368927353; called by muse, mutect2, varscan2
- KEAP1 | c.811G>A p.V271M | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV50263782, COSV50281859; called by muse, mutect2, varscan2
- KMT2D | c.16159C>T p.Q5387* | Nonsense Mutation (SNP) | VAF 9/29 reads (31%) | catalogued as COSV99980828; called by muse, mutect2, varscan2
- LNPEP | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.233); catalogued as rs778817575; called by muse, mutect2, varscan2
- MYO18B | c.908G>T p.G303V | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.015); catalogued as COSV59139622; called by muse, mutect2, varscan2
- OR2T33 | c.385C>T p.R129* | Nonsense Mutation (SNP) | VAF 8/70 reads (11%) | catalogued as rs1396360611, COSV100531888; called by muse, mutect2, varscan2
- OR5H1 | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as rs760093655; called by muse, mutect2, varscan2
- PPL | c.2489C>G p.S830C | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); catalogued as rs967408719; called by muse, mutect2, varscan2
- PRKCG | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.425); catalogued as rs760409355, COSV99669452; called by muse, mutect2, varscan2
- PRRC2C | c.8446G>C p.E2816Q (on ENST00000367742; = p.E2814Q on NM_015172.4) | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100144755; called by muse, mutect2, varscan2
- PTCH1 | c.3283G>T p.E1095* | Nonsense Mutation (SNP) | VAF 11/26 reads (42%) | catalogued as COSV59474549; called by muse, mutect2, varscan2
- PYCR2 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs777147249; called by muse, mutect2, varscan2
- SACS | c.6808G>A p.G2270S | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.866); catalogued as rs768749854; called by muse, mutect2, varscan2
- SAP18 | c.338G>A p.R113K (on ENST00000607003; = p.R132K on NM_005870.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV66822798, COSV66822847; called by muse, mutect2, varscan2
- SPATA46 | c.451C>T p.R151* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as rs769916432; called by muse, mutect2, varscan2
- SUFU | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as rs775245784, COSV64014337; called by muse, mutect2, varscan2
- TOX4 | c.1288G>A p.A430T | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated, low confidence (0.32); PolyPhen possibly damaging (0.811); catalogued as rs752952603, COSV52968502; called by mutect2, varscan2
- ABCA13 | c.14809C>A p.L4937I | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- ABCA6 | c.4220A>G p.N1407S | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- ADGRG3 | c.454G>T p.V152F | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- ADGRV1 | c.7815G>C p.L2605F | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- ATP5F1B | c.766A>T p.I256F | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- BAX | c.548C>T p.A183V | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2
- BMPR1B | c.644A>C p.Y215S | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CDH19 | c.309G>T p.Q103H | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- COL19A1 | c.2282A>T p.K761I | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL1A1 | c.1274G>T p.G425V | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- CSMD1 | c.9171C>A p.N3057K (on ENST00000520002; = p.N3056K on NM_033225.6) | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DNAH11 | c.474T>A p.H158Q | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- EHBP1 | c.2262A>C p.K754N | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EIF4A2 | c.1219A>G p.I407V | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FAM124A | c.467G>C p.G156A (on ENST00000322475 / NM_001242312.2; = p.G192A on NM_145019.4) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by mutect2, varscan2
- FBN1 | c.8171C>T p.P2724L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FLNC | c.4326C>A p.D1442E | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FREM1 | c.5755C>A p.L1919I | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- GNS | c.857A>G p.D286G | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- GPR39 | c.211C>A p.H71N | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HTR1D | c.474G>A p.M158I | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IDH2 | c.1250G>T p.G417V | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- IGHV3-38 | c.149G>T p.S50I | Missense Mutation (SNP) | VAF 43/60 reads (72%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- KCNA1 | c.1386T>A p.N462K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0.003); called by muse, mutect2
- KCNT2 | c.535A>C p.N179H | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- KDM6A | c.3767A>T p.Y1256F | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LCAT | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.74); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MGAT5B | c.416T>C p.L139P | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUC17 | c.10839C>A p.S3613R | Missense Mutation (SNP) | VAF 46/79 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- MYBPC2 | c.440G>T p.C147F | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- MYH2 | c.2595T>G p.I865M | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.165); called by muse, mutect2
- NKPD1 | c.1082C>G p.S361* | Nonsense Mutation (SNP) | VAF 4/11 reads (36%) | called by muse, mutect2, varscan2
- OLFM1 | c.176G>T p.S59I (on ENST00000371793 / NM_001282611.2; = p.S41I on NM_006334.4) | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- PAXIP1 | c.2179A>G p.M727V | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- PCDHA1 | c.832_834del p.V278del | In Frame Del (DEL) | VAF 4/29 reads (14%) | called by pindel, varscan2
- PCDHAC1 | c.61C>A p.Q21K | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- PID1 | c.395C>T p.A132V (on ENST00000354069 / NM_001330156.1; = p.A130V on NM_017933.5) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- PON1 | c.735T>G p.I245M | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- PTH1R | c.359T>A p.L120Q | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SIRT1 | c.1490A>G p.Y497C | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- SLC17A6 | c.1108G>T p.A370S | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- SLC39A12 | c.339A>T p.R113S | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- SLC9C2 | c.1769C>A p.P590Q | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- SPATC1 | c.449C>A p.T150K | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2
- UTP14C | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- YARS2 | c.683A>G p.D228G | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZFP69B | c.1508A>G p.Y503C | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF429 | c.1150C>A p.L384I | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- ZNF605 | c.1378C>A p.Q460K | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.67); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- ZNF668 | c.1141A>T p.K381* | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | called by muse, mutect2, varscan2
- ACACA | c.795C>A p.A265= | Silent (SNP) | VAF 17/35 reads (49%) | called by muse, mutect2, varscan2
- ACAD9 | c.570C>T p.A190= | Silent (SNP) | VAF 9/54 reads (17%) | called by muse, mutect2, varscan2
- BRINP1 | c.1923G>A p.S641= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs749359538, COSV56306866; called by mutect2, varscan2
- ELOA | c.1308C>T p.Y436= | Silent (SNP) | VAF 5/45 reads (11%) | called by muse, mutect2, varscan2
- FAR2 | c.27C>G p.G9= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV51727250, COSV51727447; called by muse, mutect2, varscan2
- GLUD1 | c.180C>T p.R60= | Silent (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
- GUF1 | c.858T>A p.I286= | Silent (SNP) | VAF 18/44 reads (41%) | called by muse, mutect2, varscan2
- HNRNPA1 | c.543G>C p.L181= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs199763450; called by mutect2, varscan2
- HNRNPDL | c.288A>G p.Q96= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as rs1037592355; called by muse, mutect2, varscan2
- IDH2 | c.1251C>T p.G417= | Silent (SNP) | VAF 6/35 reads (17%) | called by muse, mutect2, varscan2
- KLHL38 | c.330C>T p.A110= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as rs1413734202; called by muse, mutect2, varscan2
- MXRA5 | c.5991C>T p.P1997= | Silent (SNP) | VAF 9/22 reads (41%) | called by muse, mutect2, varscan2
- NOS1 | c.3123C>T p.F1041= | Silent (SNP) | VAF 8/37 reads (22%) | called by muse, mutect2, varscan2
- OLFM1 | c.177C>T p.S59= (on ENST00000371793 / NM_001282611.2; = p.S41= on NM_006334.4) | Silent (SNP) | VAF 16/30 reads (53%) | called by muse, mutect2, varscan2
- OR2G2 | c.499C>T p.L167= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs1277864618, COSV100189527; called by muse, mutect2, varscan2
- OR6B2 | c.285C>T p.V95= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs368904252, COSV99401706; called by mutect2, varscan2
- PCDHB13 | c.1821C>G p.L607= | Silent (SNP) | VAF 23/55 reads (42%) | called by muse, mutect2, varscan2
- PIGX | c.744A>T p.V248= | Silent (SNP) | VAF 39/90 reads (43%) | called by muse, mutect2, varscan2
- PLXNB2 | c.537C>T p.N179= | Silent (SNP) | VAF 9/14 reads (64%) | catalogued as rs370273991; called by muse, mutect2, varscan2
- PPM1K | c.537T>C p.A179= | Silent (SNP) | VAF 17/44 reads (39%) | called by muse, mutect2, varscan2
- RUSC1 | c.1974T>C p.T658= (on ENST00000368352 / NM_001105203.2; = p.T189= on NM_014328.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 9/21 reads (43%) | called by muse, mutect2, varscan2
- SIPA1L1 | c.2232G>A p.P744= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs200430873, COSV62168381; called by muse, mutect2, varscan2
- SLC20A2 | c.765A>T p.V255= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV100646083; called by muse, mutect2, varscan2
- SUPT7L | c.492A>T p.T164= | Silent (SNP) | VAF 5/27 reads (19%) | called by muse, mutect2, varscan2
- THBS2 | c.3138G>A p.T1046= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as rs750861595; called by muse, mutect2, varscan2
- TRAV40 | c.87C>G p.T29= | Silent (SNP) | VAF 6/17 reads (35%) | called by muse, varscan2
- ZNF226 | c.912A>C p.G304= | Silent (SNP) | VAF 6/29 reads (21%) | called by muse, mutect2, varscan2
- ZNF382 | c.1125G>A p.T375= | Silent (SNP) | VAF 11/18 reads (61%) | catalogued as rs148103215; called by muse, mutect2, varscan2
- FAM21FP | n.1021G>T | RNA (SNP) | VAF 19/87 reads (22%) | called by muse, mutect2, varscan2
- MIR9-1HG | n.582dup | RNA (INS) | VAF 10/24 reads (42%) | called by mutect2, pindel, varscan2
- SNORD116-18 | n.12G>A | RNA (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
